Surgical pathology report (de-identified scan), TCGA case TCGA-A7-A0CE, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-A7-A0CE-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3

carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9 lw 9/3/11

SPECIMEN

- A. Left axillary sentinel node
- B. Left breast tissue

CLINICAL NOTES

PRE-OP DIAGNOSIS: Left breast cancer

FROZEN SECTION DIAGNOSIS

- A) Lymph node, left axillary sentinel node, excision - One lymph node negative for metastatic carcinoma (0/1).

GROSS DESCRIPTION

A. Received fresh for frozen section labeled "left axillary sentinel node" are irregularly-shaped fragments of fibroadipose tissue that measure 2.5 x 2.2 x 1.2 cm. in dimension. Within the tissue a lymph node is identified that measures 1.6 cm. in maximum dimension. The lymph node is bisected and frozen as AFS1 and AFS2.

B. Received fresh in a container labeled "left breast tissue" is an 8 x 7 x 5 cm. portion of soft tan-yellow breast tissue partially covered with a 4.5 x 2 cm. tan-pink wrinkled skin ellipse. There are orienting sutures present. The specimen is inked as follows based upon the orienting sutures: superior - orange; anterior - blue; posterior - black; inferior - green. The specimen is sectioned from medial to lateral. On cut surface, there is a 2.8 x 2.8 x 2.5 cm. tan white-pink indurated mass, which is 1.1 cm. from the nearest margin, which is the inferior posterior margin.

The specimen away the mass consists of yellow adipose tissue with scant interspersed tan tissue. RS-10.

BLOCK SUMMARY: B1 - medial margin; B2 - lateral margin; B3, B4 - tumor to nearest margin (inferior/posterior); B5, 6 - tumor to posterior/deep margin; 7 - superior margin; 8 - skin to tumor; 9, 10 - specimen away from mass lesion.

[page 2 of 3]
GROSS DESCRIPTION

MICROSCOPIC DESCRIPTION

A. Serial H&E stained sections and immunostains with antibodies to keratin (AE1-AE3) are examined, and the sentinel lymph node is negative for malignancy.

B. The following template summarizes the findings in this part:

Invasive Carcinoma: Present

Histologic type: Invasive ductal carcinoma.

Histologic grade:

Overall grade: 3

Architectural score: 3

Nuclear score: 3

Mitotic score: 3

Greatest dimension (pT): 2.8 cm. (pT2)

Specimen margins: Negative

Vessel invasion: Not definitively identified

Calcification: There is necrosis within invasive carcinoma which has focal calcification.

Ductal carcinoma in situ: Present focally

Histologic pattern: Solid

Nuclear grade: 3

Central necrosis: Absent

Extensive intraductal component: Absent

Specimen margins: Negative

[page 3 of 3]
MICROSCOPIC DESCRIPTION

Description of non-tumorous breast: Changes compatible with reaction

to prior biopsy. Fibrocystic changes.

Prognostic markers: Previously performed (see

4x2, 14, 15, 20x2

[A few of the antibodies used in our laboratory may be classified as

analyte specific reagents. These antibodies are monitored and controlled in our laboratory and their performance for in vitro diagnosis is well described in the medical literature. They have not been cleared or approved by the FDA.]

DIAGNOSIS

A. Lymph node, left axially sentinel, excision -
Negative for malignancy.

B. Breast, left, biopsy -
Invasive ductal carcinoma, margins negative for malignancy.

(Electronic Signature)

--- End Of Report ---

Source: NCI Genomic Data Commons file 902f9c24-8b45-4116-9f0f-ab1b17eccfc2 (TCGA-A7-A0CE.8A853D7F-979F-4112-9659-1FDE84EF5102.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).